Somatic mutation profile of tumor specimen TCGA-D8-A27K-01A (aliquot TCGA-D8-A27K-01A-11D-A16D-09) from TCGA case TCGA-D8-A27K, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 47.7 years (17,426 days).
Specimen TCGA-D8-A27K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6bb44d25-1150-4d1d-b875-a04f0a33e2b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A27K-10A (Blood Derived Normal), aliquot TCGA-D8-A27K-10A-01D-A16D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bcd345a-8e0b-446a-98f9-50ea4841c013

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.332_334del p.K111del | In Frame Del (DEL) | VAF 12/50 reads (24%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- B4GALNT2 | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs201141534, COSV55924371; called by muse, mutect2, varscan2
- CDC5L | c.2092-1G>C p.X698_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV65175102; called by muse, mutect2, varscan2
- COL4A6 | c.4784G>T p.R1595L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV57858322; called by muse, mutect2, varscan2
- DENND5B | c.983C>G p.P328R | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60899288; called by muse, mutect2, varscan2
- FRY | c.2885C>T p.P962L | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV66564350; called by muse, mutect2
- GATA3 | c.1047_1047+1insAAAT p.I350Kfs*3 | Frame Shift Ins (INS) | VAF 5/39 reads (13%) | catalogued as COSV99062090; called by mutect2, pindel, varscan2
- GNLY | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV55702620; called by muse, mutect2
- HGS | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.706); catalogued as rs570671002, COSV61266477; called by muse, mutect2, varscan2
- IFI44 | c.679A>G p.I227V | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV66074012; called by muse, mutect2, varscan2
- LRRC61 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs765026130, COSV56230750; called by muse, mutect2, varscan2
- NBAS | c.782T>A p.V261E | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55710881; called by muse, mutect2, varscan2
- OR6C3 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.009); catalogued as rs748291525, COSV65570549, COSV65571337; called by muse, mutect2, varscan2
- PURG | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs141421913; called by muse, mutect2, varscan2
- RYR3 | c.8828C>A p.S2943* (on ENST00000389232; = p.S2944* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as COSV66776078; called by muse, mutect2, varscan2
- SEMA6A | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as rs369698820; called by muse, mutect2, varscan2
- TACC2 | c.5960C>T p.P1987L (on ENST00000334433; = p.P65L on NM_006997.4) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs532281287, COSV53275902; called by muse, mutect2
- OGDH | c.747G>A p.E249= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV56044896; called by muse, mutect2, varscan2
- OPRM1 | c.1014T>C p.Y338= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1451950575, COSV57671979; called by muse, mutect2, varscan2
- TPMT | c.618G>A p.R206= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV59428142; called by muse, mutect2, varscan2
- TTC22 | c.1002G>A p.A334= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs199739536, COSV64881095; called by muse, mutect2, varscan2
